Somatic mutation profile of tumor specimen TCGA-66-2767-01A (aliquot TCGA-66-2767-01A-01D-1522-08) from TCGA case TCGA-66-2767, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 62.7 years (22,888 days).
Specimen TCGA-66-2767-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94e12ddd-ef66-4008-ad27-e1f604dd80d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2767-11A (Solid Tissue Normal), aliquot TCGA-66-2767-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35b2898c-d8c0-4754-8472-d275c5ca3314

The open-access MAF lists 349 somatic variants for this specimen: 259 protein-altering or splice-affecting, 78 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 223, Silent 78, Nonsense Mutation 15, Frame Shift Del 11, Splice Site 8, RNA 5, Intron 4, 3'UTR 2, Frame Shift Ins 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPL | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766076920, CM980070, COSV66376963; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.62T>A p.L21H | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60623334; called by muse, mutect2, varscan2
- ABCC12 | c.1564C>G p.L522V | Missense Mutation (SNP) | VAF 172/581 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.764); catalogued as COSV60913150; called by muse, mutect2, varscan2
- ABI3BP | c.2896T>A p.Y966N | Missense Mutation (SNP) | VAF 44/243 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52533627; called by muse, mutect2, varscan2
- ACSM3 | c.469A>G p.K157E | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV55500915; called by muse, mutect2
- ADAM12 | c.2635C>T p.Q879* | Nonsense Mutation (SNP) | VAF 18/148 reads (12%) | catalogued as COSV100903512, COSV64127240; called by muse, mutect2, varscan2
- ADCY7 | c.2928C>G p.D976E | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.524); catalogued as COSV54265876; called by muse, mutect2, varscan2
- ADGRB3 | c.3622C>T p.R1208* | Nonsense Mutation (SNP) | VAF 33/181 reads (18%) | catalogued as COSV53239154, COSV99486817; called by muse, mutect2, varscan2
- ADGRF1 | c.1334A>G p.Y445C | Missense Mutation (SNP) | VAF 55/224 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV51944797; called by muse, mutect2, varscan2
- AGRN | c.3402C>A p.F1134L | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1250886116, COSV65068955; called by muse, mutect2, varscan2
- AMOT | c.2474-1G>T p.X825_splice (on ENST00000371959 / NM_001113490.1; = p.X416_splice on NM_133265.3) | Splice Site (SNP) | VAF 21/48 reads (44%) | catalogued as COSV59062460; called by muse, mutect2, varscan2
- ANK3 | c.9794T>C p.I3265T | Missense Mutation (SNP) | VAF 93/440 reads (21%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV55052899; called by muse, mutect2, varscan2
- ANKRD50 | c.3791C>G p.S1264* | Nonsense Mutation (SNP) | VAF 53/776 reads (7%) | catalogued as COSV72385389; called by muse, mutect2
- APCDD1 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 19/222 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs143954637; called by muse, mutect2
- ARID4A | c.501G>T p.K167N | Missense Mutation (SNP) | VAF 56/153 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV62163064; called by muse, mutect2, varscan2
- ARL13B | c.333G>T p.M111I | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV57397563; called by muse, mutect2, varscan2
- ARMC5 | c.859G>T p.V287F | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.961); catalogued as COSV51655846; called by muse, mutect2, varscan2
- ASTN2 | c.3554C>T p.T1185I (on ENST00000313400 / NM_001365069.1; = p.T1134I on NM_014010.5) | Missense Mutation (SNP) | VAF 22/318 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.095); catalogued as COSV56002724; called by muse, mutect2
- ATG4D | c.811G>C p.V271L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV58762413; called by muse, mutect2, varscan2
- ATP6V1B2 | c.124C>T p.Q42* | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as COSV52353270, COSV52353736; called by muse, mutect2, varscan2
- ATP7A | c.2093C>G p.S698C | Missense Mutation (SNP) | VAF 20/401 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV58444836; called by muse, mutect2
- ATP9B | c.800A>T p.D267V | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56949500; called by muse, mutect2, varscan2
- ATRN | c.544A>T p.S182C | Missense Mutation (SNP) | VAF 78/498 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV53526500; called by muse, mutect2, varscan2
- BANK1 | c.1483G>A p.D495N | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV59841383; called by muse, mutect2, varscan2
- BCAT1 | c.1003T>C p.C335R | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53910075; called by muse, mutect2, varscan2
- BCORL1 | c.911C>A p.P304Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.699); catalogued as COSV54390688, COSV99501345; called by muse, mutect2
- BRCA2 | c.6101G>A p.R2034H | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs80358849, CM074720, COSV66452039; ClinVar: uncertain significance / conflicting interpretations of pathogenicity / not provided; called by muse, mutect2, varscan2
- CACNA1E | c.6449G>C p.S2150T (on ENST00000367573 / NM_001205293.3; = p.S2107T on NM_000721.4) | Missense Mutation (SNP) | VAF 61/230 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV62389939; called by muse, mutect2, varscan2
- CACNA2D4 | c.290G>C p.G97A | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54948191; called by muse, mutect2, varscan2
- CAD | c.1204G>T p.G402W | Missense Mutation (SNP) | VAF 60/252 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53025611; called by muse, mutect2, varscan2
- CCDC171 | c.3704A>G p.K1235R | Missense Mutation (SNP) | VAF 61/169 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV66239082; called by muse, mutect2, varscan2
- CD1C | c.795G>T p.Q265H | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV63806173; called by muse, mutect2, varscan2
- CD40 | c.526C>T p.Q176* | Nonsense Mutation (SNP) | VAF 22/167 reads (13%) | catalogued as COSV64847683; called by muse, mutect2, varscan2
- CDH9 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 32/247 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV50268721, COSV50334149; called by muse, mutect2, varscan2
- CDK15 | c.176G>T p.G59V (on ENST00000652192 / NM_001366386.2; = p.G8V on NM_139158.2) | Missense Mutation (SNP) | VAF 31/363 reads (9%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.1); catalogued as rs1330297237, COSV53633434; called by muse, mutect2
- CDK17 | c.873+2T>A p.X291_splice | Splice Site (SNP) | VAF 23/106 reads (22%) | catalogued as COSV54128187; called by muse, mutect2, varscan2
- CENPP | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV65038229; called by muse, mutect2, varscan2
- CFAP206 | c.1022G>T p.G341V | Missense Mutation (SNP) | VAF 64/365 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as rs768907065, COSV51533477; called by muse, mutect2, varscan2
- CHST1 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1255269289, COSV57323095; called by muse, mutect2, varscan2
- CKAP2L | c.1304C>A p.T435K | Missense Mutation (SNP) | VAF 144/647 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as COSV56696167; called by muse, mutect2, varscan2
- COL24A1 | c.4606G>T p.G1536C | Missense Mutation (SNP) | VAF 74/254 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65304854; called by muse, mutect2, varscan2
- COL28A1 | c.1373del p.G458Efs*26 | Frame Shift Del (DEL) | VAF 28/198 reads (14%) | catalogued as COSV68085209; called by mutect2, pindel, varscan2
- CSMD3 | c.7715C>G p.P2572R (on ENST00000297405 / NM_001363185.1; = p.P2468R on NM_052900.3) | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52152773, COSV99831316; called by muse, mutect2, varscan2
- CTNNA2 | c.1418C>G p.P473R | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58146271, COSV58155739, COSV58180531; called by muse, mutect2, varscan2
- CTNNA3 | c.1885-2A>C p.X629_splice | Splice Site (SNP) | VAF 25/100 reads (25%) | catalogued as COSV65570817; called by muse, varscan2
- CYP4F12 | c.1570C>A p.Q524K | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.065); catalogued as COSV61173328; called by muse, mutect2, varscan2
- DCAF4L2 | c.586G>T p.A196S | Missense Mutation (SNP) | VAF 71/312 reads (23%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.899); catalogued as COSV60477823; called by muse, mutect2, varscan2
- DDX28 | c.1375C>T p.R459W | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768687210, COSV60105739; called by muse, mutect2, varscan2
- DDX28 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.353); catalogued as rs1478760806, COSV60105741; called by muse, mutect2
- DECR2 | c.398T>A p.V133E | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54794010; called by muse, mutect2, varscan2
- DIDO1 | c.3439G>T p.G1147C | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56619103; called by muse, mutect2, varscan2
- DNAH10 | c.3634G>T p.V1212F (on ENST00000409039; = p.V1151F on NM_207437.3) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.103); catalogued as COSV68991570; called by muse, mutect2, varscan2
- EGR2 | c.457A>G p.T153A | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV54346628; called by muse, mutect2, varscan2
- EIF2AK4 | c.2450G>A p.G817E | Missense Mutation (SNP) | VAF 27/230 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs748816386, COSV55467314; called by muse, mutect2, varscan2
- EIF3G | c.676G>A p.G226R | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1288585636, COSV53452161; called by muse, mutect2, varscan2
- EP400 | c.3373C>T p.R1125C | Missense Mutation (SNP) | VAF 45/205 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs773066144, COSV57769318, COSV57771795; called by muse, mutect2, varscan2
- ERC1 | c.2781-1G>A p.X927_splice (on ENST00000360905 / NM_178040.4; = p.X899_splice on NM_178039.4) | Splice Site (SNP) | VAF 6/112 reads (5%) | catalogued as COSV61693752; called by muse, mutect2
- F13B | c.562G>A p.G188R | Missense Mutation (SNP) | VAF 47/199 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs746985257, COSV66373317; called by muse, mutect2, varscan2
- FAM174A | c.306A>T p.E102D | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.31); catalogued as COSV57062635; called by muse, mutect2, varscan2
- FBF1 | c.2165G>A p.R722Q (on ENST00000586717; = p.R736Q on NM_001319193.1) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.078); catalogued as rs538500854, COSV59866983; called by muse, mutect2, varscan2
- FBH1 | c.3032C>A p.A1011E (on ENST00000362091 / NM_178150.3; = p.A1062E on NM_032807.4) | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV62982150, COSV62982235; called by muse, mutect2, varscan2
- FBN2 | c.886G>C p.V296L | Missense Mutation (SNP) | VAF 38/217 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV52493748, COSV52506935; called by muse, mutect2, varscan2
- FEZF1 | c.1304G>C p.G435A | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.062); catalogued as COSV58658565; called by muse, mutect2, varscan2
- FOCAD | c.107A>T p.E36V | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.329); catalogued as rs1051783615, COSV58097022; called by muse, mutect2, varscan2
- FZD3 | c.1229A>G p.N410S | Missense Mutation (SNP) | VAF 44/316 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53535095; called by muse, mutect2, varscan2
- GABRB1 | c.1214G>T p.R405L | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV54973905, COSV54977638; called by muse, mutect2, varscan2
- GCC2 | c.3913G>C p.E1305Q | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV59175567; called by muse, mutect2, varscan2
- GIMAP5 | c.457A>G p.K153E | Missense Mutation (SNP) | VAF 67/263 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV57529896; called by muse, mutect2, varscan2
- GLRA2 | c.1279C>A p.P427T | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54339233; called by muse, mutect2, varscan2
- GOSR1 | c.498A>T p.E166D | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56718697; called by muse, mutect2, varscan2
- GPI | c.1066G>A p.D356N | Missense Mutation (SNP) | VAF 53/307 reads (17%) | SIFT tolerated, low confidence (0.34); PolyPhen probably damaging (0.994); catalogued as rs887245274, CM152632, COSV62893805; called by muse, mutect2, varscan2
- GPR157 | c.374A>T p.H125L | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66233369; called by muse, mutect2, varscan2
- GPR158 | c.1192G>A p.G398S | Missense Mutation (SNP) | VAF 51/381 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66268374; called by muse, mutect2, varscan2
- GPR161 | c.1364T>C p.V455A | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV54789295; called by muse, mutect2, varscan2
- GPR32 | c.744G>T p.W248C | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.95); catalogued as COSV54514191; called by muse, mutect2
- GRIK2 | c.1372C>T p.R458* | Nonsense Mutation (SNP) | VAF 10/146 reads (7%) | catalogued as rs1271066576, COSV59710025; called by muse, mutect2
- GZMK | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.63); catalogued as rs202051718, COSV50244331; called by muse, mutect2, varscan2
- H2BC4 | c.282G>T p.E94D | Missense Mutation (SNP) | VAF 55/183 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.157); catalogued as rs747363195, COSV58415578, COSV58417740; called by muse, mutect2, varscan2
- HAPLN1 | c.294G>T p.M98I | Missense Mutation (SNP) | VAF 39/352 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as COSV99165270; called by muse, mutect2, varscan2
- HCRTR2 | c.374C>G p.S125C | Missense Mutation (SNP) | VAF 20/532 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.796); catalogued as COSV63794922, COSV63795120; called by muse, mutect2
- HERC6 | c.1151A>T p.Q384L | Missense Mutation (SNP) | VAF 81/183 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV52029179; called by muse, mutect2, varscan2
- HMCES | c.852C>G p.S284R | Missense Mutation (SNP) | VAF 54/588 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV67300299; called by muse, mutect2
- HS3ST4 | c.878G>C p.R293T | Missense Mutation (SNP) | VAF 79/269 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58810580, COSV58832687; called by muse, mutect2, varscan2
- HUWE1 | c.1990G>A p.D664N | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1557006877, COSV53341984; called by muse, mutect2, varscan2
- ICE1 | c.1711G>T p.E571* | Nonsense Mutation (SNP) | VAF 66/343 reads (19%) | catalogued as COSV56820233; called by muse, mutect2, varscan2
- IFT88 | c.190A>G p.K64E (on ENST00000319980 / NM_001318493.2; = p.K55E on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.931); catalogued as COSV60672620; called by muse, mutect2, varscan2
- IGFN1 | c.3076G>A p.G1026R (on ENST00000295591 / NM_001367841.1; = p.G3483R on NM_001164586.2) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as COSV55170465, COSV99812167; called by muse, mutect2, varscan2
- IL7R | c.707-1G>T p.X236_splice | Splice Site (SNP) | VAF 26/246 reads (11%) | catalogued as COSV100286803; called by muse, mutect2, varscan2
- INHBA | c.631G>T p.V211L | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as COSV54220806; called by muse, mutect2, varscan2
- ITFG1 | c.103C>T p.H35Y | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.187); catalogued as COSV54519078; called by muse, mutect2, varscan2
- ITGA8 | c.1158C>A p.F386L | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as COSV65226540, COSV65227301; called by muse, mutect2, varscan2
- ITLN2 | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV63537626; called by muse, mutect2, varscan2
- JAML | c.1145A>T p.K382M (on ENST00000356289 / NM_001098526.2; = p.K372M on NM_153206.3) | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as rs750659401, COSV52627188, COSV99409822; called by muse, mutect2, varscan2
- KANSL1L | c.1076A>G p.K359R | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as rs1476210177, COSV55991309; called by muse, mutect2, varscan2
- KCNA5 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV52903992; called by muse, varscan2
- KCNJ12 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as rs546877383, COSV59165730; called by muse, mutect2, varscan2
- KCNT2 | c.819G>C p.Q273H | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV54074193; called by muse, mutect2, varscan2
- KCTD3 | c.1159G>T p.E387* | Nonsense Mutation (SNP) | VAF 32/204 reads (16%) | catalogued as COSV52065950, COSV52066457; called by muse, varscan2
- KIF2B | c.1613A>T p.N538I | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV52129353; called by muse, mutect2, varscan2
- KMT2B | c.4722C>A p.H1574Q | Missense Mutation (SNP) | VAF 14/310 reads (5%) | SIFT tolerated (0.61); PolyPhen benign (0.221); catalogued as COSV55859716; called by muse, mutect2
- KRT83 | c.376A>G p.I126V | Missense Mutation (SNP) | VAF 100/412 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.639); catalogued as COSV53339481; called by muse, mutect2, varscan2
- KRTAP10-7 | c.1018T>G p.C340G | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.316); catalogued as COSV59109992; called by muse, mutect2, varscan2
- LAMP3 | c.835T>C p.S279P | Missense Mutation (SNP) | VAF 66/792 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55614393; called by muse, mutect2
- LARS1 | c.83G>A p.R28K | Missense Mutation (SNP) | VAF 17/215 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV50974226; called by muse, mutect2
- LENG9 | c.513G>C p.E171D | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV56617968; called by muse, mutect2, varscan2
- LILRB5 | c.265G>T p.V89L | Missense Mutation (SNP) | VAF 65/618 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV60256528, COSV60256919; called by muse, mutect2, varscan2
- LIPI | c.490C>G p.L164V | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV60709984, COSV60710287, COSV60712383; called by muse, mutect2
- LPIN2 | c.74C>A p.A25D | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55239027, COSV55242857; called by muse, mutect2, varscan2
- LRRTM3 | c.474G>T p.K158N | Missense Mutation (SNP) | VAF 76/302 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63664100; called by muse, mutect2, varscan2
- MAGEC1 | c.2117C>G p.S706C | Missense Mutation (SNP) | VAF 88/179 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.612); catalogued as COSV53571097; called by muse, mutect2, varscan2
- MANEA | c.233G>T p.S78I | Missense Mutation (SNP) | VAF 61/250 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV62589516; called by muse, mutect2, varscan2
- MAP1S | c.397G>T p.G133W | Missense Mutation (SNP) | VAF 63/201 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60722297; called by muse, mutect2, varscan2
- MARCHF8 | c.727G>T p.E243* | Nonsense Mutation (SNP) | VAF 37/312 reads (12%) | catalogued as COSV60571723; called by muse, mutect2, varscan2
- MATR3 | c.2038G>T p.D680Y | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.907); catalogued as COSV63076835; called by muse, mutect2, varscan2
- MUC6 | c.4061C>A p.T1354K | Missense Mutation (SNP) | VAF 44/234 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.484); catalogued as COSV70139434; called by muse, mutect2, varscan2
- MYH14 | c.1101del p.M368Wfs*13 | Frame Shift Del (DEL) | VAF 10/68 reads (15%) | catalogued as COSV51816543; called by mutect2, pindel, varscan2
- NAV3 | c.441T>A p.S147R | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV57073713; called by muse, mutect2
- NDNF | c.484T>C p.Y162H | Missense Mutation (SNP) | VAF 105/272 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1217327138, COSV65633172, COSV65634792; called by muse, mutect2, varscan2
- NDUFB8 | c.108G>T p.M36I | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.048); catalogued as COSV54511617; called by muse, mutect2, varscan2
- NEB | c.3999G>T p.K1333N | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51099869; called by muse, mutect2, varscan2
- NEBL | c.1144G>C p.E382Q | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV65802423; called by muse, mutect2, varscan2
- NEK4 | c.2489G>A p.R830H | Missense Mutation (SNP) | VAF 36/435 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as rs769126890, COSV51777064; called by muse, mutect2
- NFKB2 | c.2270C>T p.P757L | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.666); catalogued as COSV50044467; called by muse, mutect2, varscan2
- NIPSNAP3A | c.193G>C p.A65P | Missense Mutation (SNP) | VAF 32/408 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as COSV66113272; called by muse, mutect2
- NIT2 | c.511C>A p.Q171K | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as COSV67630277; called by muse, mutect2, varscan2
- NLN | c.1003G>C p.E335Q | Missense Mutation (SNP) | VAF 30/239 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.014); catalogued as COSV66765556; called by muse, mutect2, varscan2
- NPBWR1 | c.59C>A p.A20E | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV58695942, COSV58698049; called by muse, mutect2, varscan2
- NTSR1 | c.802C>A p.R268S | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT tolerated (0.96); PolyPhen benign (0.046); catalogued as rs140186245, COSV65138382; called by muse, mutect2, varscan2
- OR10AG1 | c.471G>T p.L157F | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV56632432, COSV56634934; called by muse, mutect2, varscan2
- OR10C1 | c.534C>A p.F178L (on ENST00000622521; = p.F176L on NM_013941.3) | Missense Mutation (SNP) | VAF 123/311 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as rs1215726941, COSV65822546; called by muse, mutect2, varscan2
- OR2G6 | c.364C>A p.R122S | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as rs201095356, COSV100598369, COSV58575198; called by muse, mutect2, varscan2
- OR4C12 | c.863G>A p.R288K | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.467); catalogued as rs782813832, COSV58859776, COSV58861018; called by muse, mutect2, varscan2
- OR4K1 | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 74/1208 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV53459623; called by muse, mutect2
- OR4K1 | c.225C>A p.N75K | Missense Mutation (SNP) | VAF 107/573 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs769564787, COSV53459632, COSV53461672; called by muse, mutect2, varscan2
- OR4K15 | c.953T>C p.V318A (on ENST00000305051; = p.V294A on NM_001005486.1) | Missense Mutation (SNP) | VAF 58/186 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as COSV59301050; called by muse, mutect2
- OR51V1 | c.508A>C p.N170H | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV58314861; called by muse, mutect2, varscan2
- OR5B2 | c.852C>G p.N284K | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.555); catalogued as COSV56907983; called by muse, mutect2, varscan2
- OR5H6 | c.412C>A p.R138S (on ENST00000642105; = p.R122S on NM_001005479.2) | Missense Mutation (SNP) | VAF 54/409 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV67351297; called by muse, mutect2
- OR8D2 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 69/252 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as rs774542640, COSV62488348; called by muse, mutect2, varscan2
- OR8K3 | c.410C>A p.S137* | Nonsense Mutation (SNP) | VAF 50/273 reads (18%) | catalogued as COSV57130661, COSV57131207; called by muse, mutect2, varscan2
- OR8U1 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 99/461 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100164185; called by muse, mutect2, varscan2
- OSBPL10 | c.638C>A p.P213H | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.682); catalogued as COSV101160049; called by muse, mutect2, varscan2
- OSBPL7 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs201097417; called by muse, mutect2
- OSR2 | c.649G>C p.D217H | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV52556343; called by muse, mutect2, varscan2
- OTOGL | c.1436G>A p.C479Y (on ENST00000547103; = p.C470Y on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101509549; called by muse, mutect2, varscan2
- PARPBP | c.1185G>T p.R395S | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs74958875, COSV59672857; called by muse, mutect2, varscan2
- PCDH10 | c.1650C>A p.S550R | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.185); catalogued as COSV52091732; called by muse, mutect2, varscan2
- PCDHB5 | c.19A>G p.K7E | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.009); catalogued as COSV50649594; called by muse, mutect2
- PCDHGB5 | c.916G>C p.E306Q | Missense Mutation (SNP) | VAF 24/280 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53928949; called by muse, mutect2
- PDK4 | c.327C>A p.D109E | Missense Mutation (SNP) | VAF 35/233 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV50010650; called by muse, mutect2, varscan2
- PEG3 | c.3640G>T p.A1214S | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as COSV55630514; called by muse, mutect2, varscan2
- PFAS | c.2953G>T p.G985W | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100119237; called by muse, mutect2, varscan2
- PIK3C2G | c.587G>A p.G196E | Missense Mutation (SNP) | VAF 214/491 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0.015); catalogued as COSV56805344; called by muse, mutect2, varscan2
- PITX2 | c.17del p.R6Pfs*10 | Frame Shift Del (DEL) | VAF 148/382 reads (39%) | catalogued as COSV61586030; called by mutect2, pindel*, varscan2
- PLA2G4A | c.2224G>C p.E742Q | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.134); catalogued as COSV66553274; called by muse, mutect2
- PNLIPRP3 | c.278del p.I93Kfs*24 | Frame Shift Del (DEL) | VAF 15/112 reads (13%) | catalogued as COSV65047018, COSV65049123; called by mutect2, pindel, varscan2
- POLR1F | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.145); catalogued as COSV55998203; called by muse, mutect2, varscan2
- PSG2 | c.646G>T p.E216* | Nonsense Mutation (SNP) | VAF 204/705 reads (29%) | catalogued as COSV61544977; called by muse, mutect2, varscan2
- PTCHD1 | c.1153A>T p.T385S | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV65059733; called by muse, mutect2, varscan2
- PTDSS1 | c.866G>C p.G289A | Missense Mutation (SNP) | VAF 38/576 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as COSV61264348; called by muse, mutect2
- PTDSS1 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61264202, COSV61265816; called by muse, mutect2
- PTPN3 | c.1414G>A p.G472S | Missense Mutation (SNP) | VAF 28/288 reads (10%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.727); catalogued as rs750357031, COSV52704835, COSV52707251; called by muse, mutect2
- PYGL | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 75/243 reads (31%) | catalogued as COSV53585259; called by muse, mutect2, varscan2
- RAB4A | c.637G>T p.A213S | Missense Mutation (SNP) | VAF 62/216 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs202214923, COSV64206942, COSV64206984; called by muse, mutect2, varscan2
- RANBP2 | c.2872G>C p.G958R | Missense Mutation (SNP) | VAF 38/196 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV51699270; called by muse, mutect2, varscan2
- RAPGEF2 | c.511G>T p.D171Y | Missense Mutation (SNP) | VAF 65/175 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52425126, COSV52426792; called by muse, mutect2, varscan2
- RAVER1 | c.554C>T p.S185L | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV50328892; called by muse, mutect2, varscan2
- RBM19 | c.1057A>G p.N353D | Missense Mutation (SNP) | VAF 43/257 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.075); catalogued as COSV55690589; called by muse, mutect2, varscan2
- RBMX | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as COSV57808870; called by muse, mutect2, varscan2
- RELN | c.6135G>C p.R2045S | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.423); catalogued as COSV58996222; called by muse, mutect2
- RFX6 | c.1228G>A p.V410M | Missense Mutation (SNP) | VAF 58/462 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.218); catalogued as COSV60584428; called by muse, mutect2, varscan2
- RP1 | c.525G>T p.R175S | Missense Mutation (SNP) | VAF 52/292 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV55114548; called by muse, varscan2
- RPL10L | c.513G>T p.W171C | Missense Mutation (SNP) | VAF 46/193 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV100022839; called by muse, mutect2, varscan2
- RPRML | c.232C>T p.L78F | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV59262634; called by muse, mutect2
- RTCB | c.1138G>T p.A380S | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.957); catalogued as COSV53278319, COSV99321946; called by muse, mutect2
- RUNX1T1 | c.1223G>T p.S408I (on ENST00000265814 / NM_001198628.1; = p.S381I on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/259 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.067); catalogued as COSV56143354, COSV56163184; called by muse, mutect2, varscan2
- RYR2 | c.9772C>A p.P3258T | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.193); catalogued as COSV63678514, COSV63695843; called by muse, mutect2
- RYR2 | c.11086G>A p.A3696T | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as COSV63678518; called by muse, mutect2, varscan2
- RYR2 | c.12083C>G p.S4028W | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV63678526, COSV63697805; called by muse, mutect2, varscan2
- SACS | c.6386G>T p.G2129V | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66538401; called by muse, mutect2, varscan2
- SASH1 | c.1168G>T p.E390* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | catalogued as COSV100820858, COSV66560859; called by muse, mutect2, varscan2
- SCN11A | c.2044A>G p.K682E | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56568662; called by muse, mutect2, varscan2
- SI | c.2836G>A p.D946N | Missense Mutation (SNP) | VAF 151/398 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV52273848, COSV52284064; called by muse, mutect2, varscan2
- SIGLEC14 | c.623G>C p.G208A | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55779002; called by muse, mutect2, varscan2
- SLAMF9 | c.771C>G p.I257M | Missense Mutation (SNP) | VAF 40/309 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.215); catalogued as COSV63636549; called by muse, mutect2, varscan2
- SLC12A5 | c.629G>T p.G210V (on ENST00000454036 / NM_001134771.2; = p.G187V on NM_020708.5) | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54791747; called by muse, mutect2, varscan2
- SLC13A1 | c.1262T>C p.L421P | Missense Mutation (SNP) | VAF 54/253 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52010122; called by muse, mutect2, varscan2
- SLC18A3 | c.1052G>T p.R351L | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.386); catalogued as COSV60322301, COSV60323337; called by muse, mutect2
- SLC22A1 | c.192G>T p.W64C | Missense Mutation (SNP) | VAF 45/204 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61452086; called by muse, mutect2, varscan2
- SLC36A4 | c.857G>T p.G286V | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV58395836; called by muse, varscan2
- SLC66A2 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60842885; called by muse, mutect2, varscan2
- SLC9C2 | c.1556T>G p.M519R | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV62945128; called by muse, mutect2, varscan2
- SLCO1C1 | c.793C>A p.P265T | Missense Mutation (SNP) | VAF 75/212 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.868); catalogued as COSV56871129; called by muse, mutect2, varscan2
- SLCO4C1 | c.1226T>C p.I409T | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV60514773; called by muse, mutect2
- SLITRK1 | c.1642G>T p.G548C | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as COSV65674757; called by muse, mutect2, varscan2
- SLITRK3 | c.38G>T p.R13M | Missense Mutation (SNP) | VAF 16/215 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.397); catalogued as COSV53847209; called by muse, mutect2
- SLITRK5 | c.1736A>T p.E579V | Missense Mutation (SNP) | VAF 26/298 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61522135; called by muse, mutect2
- SPAG17 | c.4117C>T p.H1373Y | Missense Mutation (SNP) | VAF 51/202 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.442); catalogued as COSV60456674; called by muse, mutect2, varscan2
- SPTA1 | c.590A>G p.H197R | Missense Mutation (SNP) | VAF 23/247 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as rs1248832413, COSV63751641; called by muse, mutect2
- ST18 | c.2851C>A p.Q951K | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV52490783; called by muse, varscan2
- STK31 | c.2068del p.X690_splice | Splice Site (DEL) | VAF 33/271 reads (12%) | catalogued as COSV63459022; called by mutect2, pindel, varscan2
- SVEP1 | c.3559C>A p.H1187N | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV57033778; called by muse, mutect2, varscan2
- SYNE1 | c.3401C>G p.S1134C (on ENST00000367255 / NM_182961.4; = p.S1141C on NM_033071.3) | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV54956096; called by muse, mutect2, varscan2
- SYNE2 | c.767C>A p.P256H | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58360425; called by muse, mutect2, varscan2
- SYNE3 | c.1069G>T p.E357* | Nonsense Mutation (SNP) | VAF 8/101 reads (8%) | catalogued as COSV62079001; called by muse, mutect2
- SYPL1 | c.540A>G p.I180M | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.138); catalogued as COSV50578815, COSV50579722; called by muse, mutect2, varscan2
- SYTL3 | c.977G>A p.C326Y (on ENST00000611299 / NM_001242394.1; = p.C258Y on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV51909504; called by muse, mutect2
- SZT2 | c.442G>T p.E148* | Nonsense Mutation (SNP) | VAF 65/201 reads (32%) | catalogued as COSV60290083; called by muse, mutect2, varscan2
- TCN2 | c.1168G>A p.G390R | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs367605153, COSV53190752; ClinVar: uncertain significance; called by muse, mutect2
- TCTN2 | c.353G>T p.C118F | Missense Mutation (SNP) | VAF 95/481 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV57632198; called by muse, mutect2, varscan2
- TECTA | c.1889G>T p.G630V | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50700357; called by muse, mutect2, varscan2
- TEX13A | c.330C>A p.D110E | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.243); catalogued as COSV61151741; called by muse, mutect2, varscan2
- TMEM131 | c.5644G>A p.E1882K | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.248); catalogued as rs764886341, COSV51773885; called by muse, mutect2, varscan2
- TMEM19 | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 101/339 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV56999627; called by muse, mutect2, varscan2
- TNRC18 | c.5324C>T p.P1775L | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV68164575; called by muse, mutect2, varscan2
- TNXB | c.8264G>A p.S2755N (on ENST00000647633; = p.S2508N on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.736); catalogued as COSV64477239; called by muse, mutect2
- TPI1 | c.802C>T p.L268F (on ENST00000229270; = p.L231F on NM_000365.6) | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as COSV51290108, COSV99222981; called by muse, mutect2, varscan2
- TPR | c.2960G>A p.R987H | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs371802543, COSV66600737; called by muse, mutect2, varscan2
- TRHDE | c.2520G>C p.W840C | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53840273, COSV53856355; called by muse, mutect2, varscan2
- TTC14 | c.1942G>C p.E648Q | Missense Mutation (SNP) | VAF 25/262 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.963); catalogued as COSV56010579; called by muse, mutect2
- TTC24 | c.1304G>A p.G435E | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV63997458; called by muse, mutect2, varscan2
- TTN | c.5503C>A p.Q1835K (on ENST00000591111; = p.Q1789K on NM_003319.4) | Missense Mutation (SNP) | VAF 74/355 reads (21%) | PolyPhen benign (0.083); catalogued as rs537070177, COSV59988634, COSV60160442; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TUBA3C | c.1270G>T p.D424Y | Missense Mutation (SNP) | VAF 58/234 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV68028035; called by muse, mutect2, varscan2
- TXLNB | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV62727269; called by muse, mutect2, varscan2
- UGT2B11 | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 13/234 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV71423230, COSV71423319; called by muse, mutect2
- USH2A | c.9933A>T p.E3311D | Missense Mutation (SNP) | VAF 76/273 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as COSV56356104; called by muse, mutect2, varscan2
- USP13 | c.1421del p.R474Lfs*25 | Frame Shift Del (DEL) | VAF 68/188 reads (36%) | catalogued as COSV99831646; called by mutect2, varscan2
- VCAN | c.8400A>C p.E2800D | Missense Mutation (SNP) | VAF 27/341 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV54102763; called by muse, mutect2
- VEZF1 | c.38A>G p.H13R | Missense Mutation (SNP) | VAF 49/204 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV51968022; called by muse, varscan2
- VPS13B | c.11306T>C p.I3769T | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763287127, COSV62136869; called by muse, mutect2, varscan2
- WDR62 | c.3512C>T p.T1171M | Missense Mutation (SNP) | VAF 60/231 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.72); catalogued as COSV54334003; called by muse, mutect2, varscan2
- ZAN | c.7384G>T p.G2462W | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100769256, COSV61807729; called by muse, mutect2
- ZC3H18 | c.254T>A p.V85E | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV56324039; called by muse, mutect2, varscan2
- ZEB1 | c.1560A>C p.K520N | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV58041697; called by muse, mutect2, varscan2
- ZFHX4 | c.2258G>T p.C753F | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV50677721; called by muse, mutect2, varscan2
- ZKSCAN2 | c.1808G>T p.R603M | Missense Mutation (SNP) | VAF 89/294 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.111); catalogued as COSV60156363; called by muse, mutect2, varscan2
- ZNF276 | c.1281-2A>T p.X427_splice (on ENST00000443381 / NM_001113525.2; = p.X352_splice on NM_152287.4) | Splice Site (SNP) | VAF 18/160 reads (11%) | catalogued as COSV57067389; called by muse, mutect2, varscan2
- ZNF292 | c.6674C>G p.S2225C | Missense Mutation (SNP) | VAF 30/264 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.819); catalogued as COSV60538098; called by muse, mutect2, varscan2
- ZNF415 | c.322A>G p.N108D | Missense Mutation (SNP) | VAF 9/248 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV54700465; called by muse, mutect2
- ZNF536 | c.277G>C p.D93H | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV62822348; called by muse, mutect2, varscan2
- ZNF708 | c.709T>A p.S237T | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.487); catalogued as COSV63607212; called by muse, mutect2, varscan2
- ZNF791 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as COSV58480595; called by muse, mutect2, varscan2
- ZNF827 | c.196T>A p.S66T | Missense Mutation (SNP) | VAF 51/163 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV65226243; called by muse, mutect2, varscan2
- CCDC50 | c.794G>T p.W265L | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0.001); called by muse, mutect2
- COL4A6 | c.3749dup p.L1250Ffs*11 | Frame Shift Ins (INS) | VAF 35/114 reads (31%) | called by mutect2, pindel, varscan2
- FAT1 | c.10355_10373del p.N3452Tfs*6 | Frame Shift Del (DEL) | VAF 24/62 reads (39%) | called by mutect2, pindel
- FCGBP | c.8621G>T p.C2874F | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- IGKV2D-28 | c.141G>T p.Q47H | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.047); called by mutect2, varscan2
- IL1RL2 | c.151del p.E51Kfs*4 | Frame Shift Del (DEL) | VAF 28/200 reads (14%) | called by mutect2, pindel, varscan2
- MED15 | c.1825del p.V609Cfs*38 (on ENST00000263205 / NM_001003891.3; = p.V569Cfs*38 on NM_015889.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/71 reads (20%) | called by mutect2, pindel
- MRC1 | c.1738A>G p.I580V | Missense Mutation (SNP) | VAF 51/396 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR2D2 | c.565_572dup p.T192Pfs*17 | Frame Shift Ins (INS) | VAF 18/108 reads (17%) | called by mutect2, varscan2
- PCDHB9 | c.1357del p.Q453Kfs*89 | Frame Shift Del (DEL) | VAF 24/234 reads (10%) | called by mutect2, varscan2
- SPAG5 | c.46del p.Q16Rfs*7 | Frame Shift Del (DEL) | VAF 18/143 reads (13%) | called by mutect2, pindel, varscan2
- SUPT20HL1 | c.1819G>T p.G607C | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SYNRG | c.3500G>A p.G1167D | Missense Mutation (SNP) | VAF 76/455 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRAV9-1 | c.95C>G p.P32R | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF431 | c.1661del p.N554Tfs*33 | Frame Shift Del (DEL) | VAF 35/119 reads (29%) | called by mutect2, pindel, varscan2
- ZNF605 | c.137-1G>C p.X46_splice | Splice Site (SNP) | VAF 8/151 reads (5%) | called by muse, mutect2
- AAAS | c.54A>T p.L18= | Silent (SNP) | VAF 156/566 reads (28%) | catalogued as COSV52932679; called by muse, mutect2, varscan2
- ACHE | c.1461G>C p.G487= | Silent (SNP) | VAF 21/99 reads (21%) | catalogued as COSV53816731, COSV99574575; called by muse, mutect2, varscan2
- ADGRB3 | c.1185T>G p.A395= | Silent (SNP) | VAF 18/206 reads (9%) | catalogued as rs376951955, COSV65391140; called by muse, mutect2
- AGT | c.1407C>A p.A469= | Silent (SNP) | VAF 22/168 reads (13%) | catalogued as COSV64184334; called by muse, mutect2, varscan2
- ALS2 | c.45G>A p.K15= | Silent (SNP) | VAF 39/104 reads (38%) | catalogued as COSV51886116; called by muse, mutect2, varscan2
- AP1B1 | c.2619G>A p.A873= | Silent (SNP) | VAF 36/147 reads (24%) | catalogued as rs770695714, COSV58015393; called by muse, mutect2, varscan2
- APOA5 | c.552C>A p.T184= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV57062955, COSV57065307; called by muse, mutect2, varscan2
- APOOL | c.339G>A p.P113= | Silent (SNP) | VAF 17/28 reads (61%) | catalogued as rs1367755665, COSV64271494; called by muse, mutect2, varscan2
- ARVCF | c.246G>A p.T82= | Silent (SNP) | VAF 20/107 reads (19%) | catalogued as COSV54268527; called by mutect2, varscan2
- ATP13A3 | c.3072T>G p.G1024= | Silent (SNP) | VAF 18/186 reads (10%) | catalogued as rs201703070, COSV55461411, COSV55462487; called by muse, mutect2, varscan2
- CAND2 | c.2970C>T p.V990= (on ENST00000456430 / NM_001162499.2; = p.V897= on NM_012298.3) | Silent (SNP) | VAF 36/114 reads (32%) | catalogued as COSV55988953; called by muse, mutect2, varscan2
- CD1E | c.138C>T p.A46= | Silent (SNP) | VAF 27/247 reads (11%) | catalogued as COSV63770690; called by muse, mutect2, varscan2
- CHAT | c.330C>A p.P110= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV60325256; called by muse, mutect2
- COL5A1 | c.1995C>T p.D665= | Silent (SNP) | VAF 16/226 reads (7%) | catalogued as rs765776659, COSV65667844; called by muse, mutect2
- DCAF4L2 | c.945C>A p.S315= | Silent (SNP) | VAF 34/170 reads (20%) | catalogued as COSV100151436, COSV60479057; called by muse, mutect2, varscan2
- DLL3 | c.987G>T p.G329= | Silent (SNP) | VAF 37/273 reads (14%) | catalogued as COSV99219643; called by muse, mutect2, varscan2
- DNAH1 | c.768G>C p.R256= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV70228139; called by muse, mutect2, varscan2
- EML1 | c.348G>T p.G116= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as COSV51743605; called by muse, mutect2, varscan2
- F5 | c.84G>T p.A28= | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as COSV55250643; called by muse, mutect2, varscan2
- FAAP100 | c.1929C>T p.S643= | Silent (SNP) | VAF 34/162 reads (21%) | catalogued as COSV59884821; called by muse, mutect2, varscan2
- FRYL | c.8325C>G p.L2775= | Silent (SNP) | VAF 52/189 reads (28%) | catalogued as rs1464004077, COSV51944653; called by muse, mutect2, varscan2
- GPR4 | c.759C>A p.G253= | Silent (SNP) | VAF 42/108 reads (39%) | catalogued as COSV59916663; called by muse, mutect2, varscan2
- GRM8 | c.1467C>A p.G489= | Silent (SNP) | VAF 71/372 reads (19%) | catalogued as COSV58818293; called by muse, mutect2, varscan2
- HK1 | c.2397G>A p.Q799= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV53856470, COSV53857387; called by muse, mutect2, varscan2
- HSPBP1 | c.960C>T p.L320= | Silent (SNP) | VAF 76/242 reads (31%) | catalogued as rs749395793, COSV55333974, COSV55334995; called by muse, mutect2, varscan2
- IFT140 | c.2391C>A p.L797= | Silent (SNP) | VAF 26/414 reads (6%) | catalogued as COSV54152337; called by muse, mutect2
- IRF2 | c.639G>A p.P213= | Silent (SNP) | VAF 65/175 reads (37%) | catalogued as rs758246792, COSV101165803, COSV66928411; called by muse, mutect2, varscan2
- ITGAD | c.960C>T p.A320= | Silent (SNP) | VAF 15/147 reads (10%) | catalogued as rs145577588; called by muse, mutect2, varscan2
- ITPKB | c.858G>C p.R286= | Silent (SNP) | VAF 44/153 reads (29%) | catalogued as COSV55259851; called by muse, varscan2
- LATS1 | c.576G>T p.P192= | Silent (SNP) | VAF 22/147 reads (15%) | catalogued as COSV53589392; called by muse, mutect2, varscan2
- LRP12 | c.2049G>T p.T683= | Silent (SNP) | VAF 29/141 reads (21%) | catalogued as COSV99408522; called by muse, mutect2, varscan2
- LRRIQ4 | c.354C>T p.H118= | Silent (SNP) | VAF 16/272 reads (6%) | catalogued as rs776478957, COSV61618617; called by muse, mutect2
- MARVELD3 | c.514C>A p.R172= | Silent (SNP) | VAF 18/135 reads (13%) | catalogued as COSV51703984, COSV51704500; called by muse, mutect2, varscan2
- MCHR1 | c.738T>G p.P246= | Silent (SNP) | VAF 31/192 reads (16%) | catalogued as COSV50760919; called by muse, mutect2, varscan2
- MYH14 | c.1800G>T p.A600= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as rs903381620, COSV99223062, COSV99224573; called by muse, mutect2, varscan2
- NCOR2 | c.33G>T p.T11= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as rs369322766, COSV100657401, COSV62296497; called by muse, mutect2, varscan2
- NLRP7 | c.678G>A p.L226= | Silent (SNP) | VAF 19/190 reads (10%) | catalogued as rs1272931981, COSV60173039; called by muse, mutect2, varscan2
- NRIP2 | c.303G>A p.P101= | Silent (SNP) | VAF 19/310 reads (6%) | catalogued as rs774088885, COSV61701417, COSV61702025; called by muse, mutect2
- OOSP2 | c.181C>A p.R61= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as COSV53928154, COSV53928565; called by muse, mutect2, varscan2
- OR10T2 | c.781C>A p.R261= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as rs372699275, COSV57780839; called by muse, mutect2, varscan2
- OR5B3 | c.420T>A p.A140= | Silent (SNP) | VAF 39/195 reads (20%) | catalogued as COSV58676880; called by muse, mutect2, varscan2
- OR5J2 | c.174C>A p.P58= | Silent (SNP) | VAF 111/617 reads (18%) | catalogued as COSV100399334, COSV56621442; called by muse, mutect2, varscan2
- OR8B8 | c.624T>C p.G208= | Silent (SNP) | VAF 50/147 reads (34%) | catalogued as COSV60143567, COSV60144296; called by muse, mutect2, varscan2
- OTOA | c.1212G>A p.L404= (on ENST00000286149; = p.L390= on NM_144672.4) | Silent (SNP) | VAF 12/118 reads (10%) | catalogued as COSV53752149; called by muse, mutect2
- PCDHB3 | c.1347C>A p.P449= | Silent (SNP) | VAF 56/211 reads (27%) | catalogued as COSV50569020, COSV50574942; called by muse, mutect2, varscan2
- PMEPA1 | c.552C>T p.R184= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as rs1237005481, COSV55692848; called by muse, mutect2, varscan2
- PSD4 | c.774G>A p.E258= | Silent (SNP) | VAF 41/170 reads (24%) | catalogued as COSV55525863; called by muse, mutect2, varscan2
- RAD17 | c.522C>T p.F174= (on ENST00000380774 / NM_133339.2; = p.F163= on NM_002873.1) | Silent (SNP) | VAF 13/181 reads (7%) | catalogued as COSV51457264; called by muse, mutect2
- RICTOR | c.1818C>T p.C606= | Silent (SNP) | VAF 28/252 reads (11%) | catalogued as COSV57120459; called by muse, mutect2, varscan2
- RNF157 | c.1995G>A p.E665= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV99487572; called by mutect2, varscan2
- RP1 | c.486C>A p.G162= | Silent (SNP) | VAF 40/202 reads (20%) | catalogued as rs767981824, COSV55114004, COSV55114541; called by muse, varscan2
- RP1L1 | c.5958C>T p.T1986= | Silent (SNP) | VAF 134/542 reads (25%) | catalogued as COSV66754049; called by muse, mutect2, varscan2
- SCN2A | c.2322C>A p.L774= | Silent (SNP) | VAF 65/248 reads (26%) | catalogued as COSV51835706, COSV51838016; called by muse, mutect2, varscan2
- SERPINA7 | c.885A>G p.L295= | Silent (SNP) | VAF 158/386 reads (41%) | catalogued as COSV59665483; called by muse, mutect2, varscan2
- SETD2 | c.5056C>A p.R1686= | Silent (SNP) | VAF 15/206 reads (7%) | catalogued as COSV100340335; called by muse, mutect2
- SIK3 | c.2376C>G p.P792= (on ENST00000445177 / NM_001366686.2; = p.P750= on NM_025164.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/149 reads (26%) | catalogued as COSV52612499; called by muse, mutect2, varscan2
- SIPA1L2 | c.2499G>T p.L833= | Silent (SNP) | VAF 77/284 reads (27%) | catalogued as COSV53388376; called by muse, mutect2, varscan2
- SLC12A1 | c.1236C>A p.P412= | Silent (SNP) | VAF 59/418 reads (14%) | catalogued as COSV100372646; called by muse, mutect2, varscan2
- SLC12A3 | c.1692C>T p.Y564= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as rs1397797539, COSV52634097; called by muse, mutect2
- SLITRK5 | c.1959C>G p.G653= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV100280391, COSV61522140; called by muse, mutect2, varscan2
- SPATA31A3 | c.2163A>T p.T721= | Silent (SNP) | VAF 30/274 reads (11%) | called by muse, mutect2, varscan2
- SPATA31D1 | c.2745G>T p.L915= | Silent (SNP) | VAF 8/122 reads (7%) | catalogued as COSV61194671; called by muse, mutect2
- SPTBN1 | c.2043G>T p.R681= | Silent (SNP) | VAF 21/98 reads (21%) | catalogued as COSV61687558; called by muse, mutect2, varscan2
- STEAP1 | c.783C>T p.S261= | Silent (SNP) | VAF 43/471 reads (9%) | catalogued as COSV51881384; called by muse, mutect2
- TEX55 | c.171A>T p.L57= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as COSV55210830; called by muse, mutect2, varscan2
- TNFRSF10D | c.702G>A p.K234= | Silent (SNP) | VAF 13/104 reads (13%) | catalogued as COSV57035362, COSV57037381; called by muse, mutect2, varscan2
- TNR | c.4074C>T p.F1358= | Silent (SNP) | VAF 29/199 reads (15%) | catalogued as COSV54880192; called by muse, mutect2, varscan2
- TSGA10 | c.1854T>C p.N618= | Silent (SNP) | VAF 25/115 reads (22%) | catalogued as rs778176906, COSV61822846; called by muse, mutect2, varscan2
- TTC27 | c.408G>T p.L136= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as COSV58650706; called by muse, varscan2
- VCAM1 | c.627A>T p.T209= | Silent (SNP) | VAF 49/183 reads (27%) | catalogued as COSV54118828; called by muse, mutect2, varscan2
- ZBTB1 | c.1410T>C p.C470= | Silent (SNP) | VAF 71/240 reads (30%) | catalogued as COSV62437796; called by muse, mutect2, varscan2
- ZBTB11 | c.832C>T p.L278= | Silent (SNP) | VAF 35/201 reads (17%) | catalogued as COSV57244769; called by muse, mutect2, varscan2
- ZFP28 | c.1512C>T p.P504= | Silent (SNP) | VAF 41/160 reads (26%) | catalogued as rs200309652, COSV56735451; called by muse, mutect2, varscan2
- ZIC1 | c.192C>T p.F64= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as COSV51552496; called by muse, mutect2, varscan2
- ZNF565 | c.1281C>T p.G427= (on ENST00000355114; = p.G387= on NM_152477.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 32/366 reads (9%) | catalogued as rs745721434, COSV58410700; called by muse, mutect2
- ZNF676 | c.199A>C p.R67= (on ENST00000650058; = p.R35= on NM_001001411.3) | Silent (SNP) | VAF 50/161 reads (31%) | catalogued as COSV68092770; called by muse, mutect2, varscan2
- ZNF8 | c.456G>A p.E152= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV52187286; called by muse, mutect2, varscan2
- ZZEF1 | c.8112G>T p.S2704= | Silent (SNP) | VAF 49/215 reads (23%) | catalogued as rs373957147, COSV67557011; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840148 C>A | 5'Flank (SNP) | VAF 11/90 reads (12%) | catalogued as COSV58332472; called by muse, mutect2, varscan2
- CFAP61 | c.567-5316C>A | Intron (SNP) | VAF 19/219 reads (9%) | catalogued as rs187730443; called by muse, mutect2
- DLG2 | c.205-65648C>T | Intron (SNP) | VAF 25/203 reads (12%) | catalogued as COSV99720873; called by muse, mutect2, varscan2
- LANCL3 | c.1103+913C>G | Intron (SNP) | VAF 11/79 reads (14%) | catalogued as COSV101065809; called by muse, mutect2, varscan2
- NRG1 | c.502+31071C>T | Intron (SNP) | VAF 20/224 reads (9%) | catalogued as COSV99829971; called by muse, mutect2
- OR2W5 | n.553C>A | RNA (SNP) | VAF 19/169 reads (11%) | called by muse, mutect2, varscan2
- OR2W5 | n.939C>A | RNA (SNP) | VAF 43/301 reads (14%) | called by muse, mutect2, varscan2
- OR52A4P | n.945C>T | RNA (SNP) | VAF 12/71 reads (17%) | called by muse, mutect2, varscan2
- OTOF | c.*129G>T | 3'UTR (SNP) | VAF 19/98 reads (19%) | catalogued as CD165340, COSV99719424; called by muse, mutect2, varscan2
- SLC35A3 | c.*375G>A | 3'UTR (SNP) | VAF 15/151 reads (10%) | catalogued as COSV64515853; called by muse, mutect2
- SNORD115-2 | n.82C>A | RNA (SNP) | VAF 47/277 reads (17%) | called by muse, mutect2, varscan2
- SSPOP | n.10418T>C | RNA (SNP) | VAF 8/40 reads (20%) | catalogued as COSV65128910; called by muse, mutect2, varscan2
